Gene-level copy-number profile of tumor specimen AP-AAFC-C3 from APOLLO case AP-AAFC, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-AAFC-C3: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2dab3c2c-aa51-4ed1-b9bc-a4a1c78a459f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-AAFC-N5 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/a4a87d13-9ba2-4dec-96ff-a93e3af2f944

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 129; copy number 1: 9; copy number 2: 443; copy number 3: 10,658; copy number 4: 11,376; copy number 5: 9,306; copy number 6: 16,857; copy number 7: 7,383; copy number 8: 1,467; copy number 9: 740; copy number 10: 11; copy number 11: 2; copy number 12: 2; copy number 13: 7.

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:63,509,303–63,510,165, 1 gene: PHKG1P2.
- chr8:7,696,830–7,741,396, 6 genes: AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P.
- chr8:7,881,392–8,226,614, 23 genes: DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:12,115,767–12,206,389, 10 genes: FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1, ENPP7P12.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:19,705,338–25,089,151, 88 genes (within-gene range 0–4) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:140,177,184–140,293,339, 5 genes, copy number 13: KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6.
- chr7:158,623,188–158,704,804, 2 genes, copy number 13: THAP5P1, NCAPG2.

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
